Somatic mutation profile of cancer-model specimen HCM-BROD-0124-C25-85A (3D Organoid, passage 11; aliquot HCM-BROD-0124-C25-85A-01D-A786-36), derived from the primary tumor of HCMI case HCM-BROD-0124-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 60.5 years (22,096 days).
Specimen HCM-BROD-0124-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 11.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 44437220-18fa-4d38-8e4c-adfeec1a30e2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0124-C25-10A (Blood Derived Normal), aliquot HCM-BROD-0124-C25-10A-01D-A78W-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b1f722e-f3a1-40ce-825b-f5e2b5eb45e8

The open-access MAF lists 41 somatic variants for this specimen: 30 protein-altering or splice-affecting, 8 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 8, Nonsense Mutation 4, Intron 2, Frame Shift Ins 1, Splice Site 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 150/347 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACSS2 | c.566T>C p.I189T | Missense Mutation (SNP) | VAF 55/105 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); catalogued as rs768218171; called by muse, varscan2
- ARMH4 | c.2221C>T p.R741* | Nonsense Mutation (SNP) | VAF 147/303 reads (49%) | catalogued as rs375790812; called by muse, mutect2, varscan2
- ATP8A2 | c.1339G>A p.G447R | Missense Mutation (SNP) | VAF 85/182 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs1488656371; called by muse, mutect2, varscan2
- CABP4 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 153/302 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as COSV100351612; called by muse, mutect2, varscan2
- CDH2 | c.2675C>T p.P892L | Missense Mutation (SNP) | VAF 227/227 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758658207; called by muse, mutect2, varscan2
- CEP170 | c.4706A>G p.N1569S | Missense Mutation (SNP) | VAF 127/215 reads (59%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.978); catalogued as rs777193870; called by muse, mutect2, varscan2
- KEL | c.1933G>A p.A645T | Missense Mutation (SNP) | VAF 312/693 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs767499938; called by muse, mutect2, varscan2
- MUC4 | c.11591C>A p.S3864* | Nonsense Mutation (SNP) | VAF 247/868 reads (28%) | catalogued as COSV57774569; called by muse, mutect2, varscan2
- PLXNA4 | c.3425C>T p.P1142L | Missense Mutation (SNP) | VAF 222/477 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753895846; called by muse, mutect2, varscan2
- PTPRT | c.3481T>A p.Y1161N | Missense Mutation (SNP) | VAF 99/206 reads (48%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.993); catalogued as rs779305073; called by muse, mutect2, varscan2
- RNASE9 | c.266G>A p.G89E | Missense Mutation (SNP) | VAF 73/138 reads (53%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100141089; called by muse, mutect2, varscan2
- SLC25A48 | c.524C>T p.A175V (on ENST00000650267; = p.A121V on NM_001349335.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 112/208 reads (54%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs756058753, COSV50847980, COSV50848980; called by mutect2, varscan2
- STAP1 | c.483G>C p.E161D | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.115); catalogued as rs1171195502, COSV55327183; called by muse, mutect2, varscan2
- TP53 | c.997del p.R333Vfs*12 | Frame Shift Del (DEL) | VAF 150/210 reads (71%) | catalogued as CM137619, COSV52774724; called by mutect2, pindel, varscan2
- VWA3B | c.1283C>T p.P428L | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs558379576; called by muse, mutect2, varscan2
- AP1G2 | c.2329A>G p.N777D | Missense Mutation (SNP) | VAF 141/293 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- BICRA | c.4402G>T p.G1468W | Missense Mutation (SNP) | VAF 258/259 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C19orf54 | c.670G>T p.E224* | Nonsense Mutation (SNP) | VAF 97/385 reads (25%) | called by muse, mutect2, varscan2
- CNNM3 | c.1606T>G p.F536V | Missense Mutation (SNP) | VAF 58/157 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- DNAH1 | c.9782delinsCT p.R3261Pfs*58 | Frame Shift Ins (INS) | VAF 93/248 reads (38%) | called by pindel, varscan2*
- GALNT5 | c.2683G>A p.V895M | Missense Mutation (SNP) | VAF 132/300 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- GRHL2 | c.891+1G>A p.X297_splice | Splice Site (SNP) | VAF 490/761 reads (64%) | called by muse, mutect2, varscan2
- HECTD2 | c.382C>T p.Q128* | Nonsense Mutation (SNP) | VAF 98/181 reads (54%) | called by muse, mutect2, varscan2
- HOXD8 | c.695A>G p.H232R | Missense Mutation (SNP) | VAF 77/413 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HTR1B | c.235A>G p.K79E | Missense Mutation (SNP) | VAF 140/153 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIF1C | c.2368G>C p.D790H | Missense Mutation (SNP) | VAF 101/102 reads (99%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- LRRK2 | c.6895C>T p.P2299S | Missense Mutation (SNP) | VAF 133/298 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- MKNK2 | c.1262A>T p.Q421L | Missense Mutation (SNP) | VAF 189/190 reads (99%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PANK1 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 69/224 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- ACSM4 | c.147T>A p.P49= | Silent (SNP) | VAF 120/682 reads (18%) | called by muse, mutect2, varscan2
- CLUH | c.2961C>A p.A987= (on ENST00000435359; = p.A1026= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/270 reads (4%) | called by muse, mutect2
- IGSF8 | c.537G>A p.G179= | Silent (SNP) | VAF 176/463 reads (38%) | called by muse, mutect2, varscan2
- LRFN1 | c.603C>T p.I201= | Silent (SNP) | VAF 13/268 reads (5%) | catalogued as rs1195978552, COSV50480688; called by muse, mutect2
- PCDHB3 | c.1965C>T p.T655= | Silent (SNP) | VAF 326/719 reads (45%) | catalogued as rs781913012, COSV50577078; called by muse, mutect2, varscan2
- PHOX2B | c.519C>A p.G173= | Silent (SNP) | VAF 16/420 reads (4%) | called by muse, mutect2
- SCGN | c.306C>T p.N102= | Silent (SNP) | VAF 55/61 reads (90%) | catalogued as rs1173035598; called by muse, mutect2, varscan2
- SLMAP | c.112C>A p.R38= | Silent (SNP) | VAF 263/342 reads (77%) | catalogued as COSV99909258; called by muse, mutect2, varscan2
- NLRP13 | chr19:55932318 C>A | 5'Flank (SNP) | VAF 101/101 reads (100%) | called by muse, mutect2, varscan2
- PSPN | c.148+43C>A | Intron (SNP) | VAF 11/107 reads (10%) | catalogued as rs1165299069; called by muse, mutect2, varscan2
- SNTB1 | c.789-22366T>C | Intron (SNP) | VAF 232/348 reads (67%) | called by muse, mutect2, varscan2
